Somatic mutation profile of tumor specimen TARGET-30-PARGKK-01A (aliquot TARGET-30-PARGKK-01A-01D) from TARGET case TARGET-30-PARGKK, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 6.1 years (2,241 days).
Specimen TARGET-30-PARGKK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e23ce808-e5bf-496f-8c63-c1d02e156a1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARGKK-10A (Blood Derived Normal), aliquot TARGET-30-PARGKK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8167c120-c196-4662-b99d-62500c08239b

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Nonsense Mutation 4, Silent 3, In Frame Del 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TNFAIP3 | c.1809del p.T604Rfs*93 | Frame Shift Del (DEL) | VAF 37/97 reads (38%) | catalogued as rs864321683; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADD1 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs569737530, COSV53269830; called by muse, mutect2, varscan2
- CYP4F8 | c.1249G>C p.G417R | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57854235; called by muse, mutect2, varscan2
- FBN1 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV57318862; called by muse, mutect2, varscan2
- GAS2L2 | c.1946G>A p.G649D | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs112674267; called by muse, mutect2, varscan2
- GDPD4 | c.561C>A p.C187* | Nonsense Mutation (SNP) | VAF 38/156 reads (24%) | catalogued as COSV60019912, COSV60020336; called by muse, mutect2, varscan2
- GSTA1 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV58015539; called by muse, mutect2, varscan2
- HMCN1 | c.5708C>A p.A1903E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.572); catalogued as COSV54905687; called by muse, mutect2, varscan2
- HRNR | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV64258936; called by muse, mutect2, varscan2
- HTT | c.5111A>G p.Y1704C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.302); catalogued as rs1433865496, COSV61863199; called by muse, mutect2, varscan2
- PCDH11Y | c.3813G>T p.L1271F | Missense Mutation (SNP) | VAF 84/121 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV53082374; called by muse, mutect2, varscan2
- PDGFA | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 61/400 reads (15%) | catalogued as COSV63279825; called by muse, mutect2, varscan2
- PRKAA2 | c.97G>T p.G33* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV64804199; called by muse, varscan2
- PSG1 | c.635C>A p.A212E | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1349927352; called by muse, mutect2
- RABGGTA | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52863458; called by muse, mutect2, varscan2
- RAI14 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54295879; called by muse, mutect2, varscan2
- SIAH1 | c.494T>C p.F165S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53522986; called by muse, mutect2, varscan2
- TMEM80 | c.301G>A p.A101T (on ENST00000526170 / NM_001276274.1; = p.A163T on NM_174940.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.292); catalogued as rs762743946, COSV59348147; called by muse, mutect2, varscan2
- ZAN | c.3317C>A p.A1106E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV61810081; called by muse, varscan2
- ASPM | c.6454G>C p.A2152P | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- LY9 | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- OR51M1 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2
- TOPBP1 | c.1509_1523del p.K505_A509del | In Frame Del (DEL) | VAF 3/27 reads (11%) | called by mutect2*, pindel
- NINL | c.2967C>A p.G989= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV54003456; called by muse, mutect2, varscan2
- TACC2 | c.4362G>A p.G1454= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV57757678; called by muse, mutect2, varscan2
- ZNF532 | c.2901G>A p.G967= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100265921, COSV60173507; called by muse, mutect2, varscan2
- FMN1 | c.2044-2117C>T | Intron (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
